MMRF case MMRF_1519 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cd91e38c-1d2a-4534-8765-bfb9f0541338

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 88 years; Vital status: Dead; Days to death: 647 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 88.1 years (32,171 days); ISS stage: III; Days to last known disease status: 647 days (1.8 years); Days to last follow up: 647 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 6 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 195 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 13 days; Days to treatment end: 195 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 81 days; Days to treatment end: 391 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 265 days; Days to treatment end: 307 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 269 days; Days to treatment end: 647 days (1.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 647.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 4.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 892 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.776 mg/dL; Immunoglobulin G 52.8 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 6.87 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 125 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.43 mmol/L; Albumin 31 g/L; Total Protein 10.2 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 3.44 mg/dL.
- Day 79 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 8.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Immunoglobulin G 25.3 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 5.35 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 171 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 174 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 6.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.37 mg/dL; Immunoglobulin G 16.8 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.67 mmol/L.
- Day 265 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.96 mg/dL; Immunoglobulin G 20.1 g/L; Immunoglobulin A 1.74 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 4.77 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.3 mmol/L; Albumin 28 g/L; Total Protein 6.8 g/dL; Glucose 10.8 mmol/L.
- Day 361: M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.79 mg/dL; Immunoglobulin G 18.6 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.42 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 5.39 mmol/L.
- Day 461: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 19 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.49 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 256 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.43 mmol/L; Albumin 31 g/L; Total Protein 7 g/dL; Glucose 5.72 mmol/L.
- Day 524: M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 19.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 1.86 g/L; Immunoglobulin M 0.64 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 28 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 627 (ECOG 2): M Protein 1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.65 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 1.75 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.1 ×10⁹/L; Absolute Neutrophil 7.1 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 29 g/L; Total Protein 6.5 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day 0: Weight: 114 kg; Height: 193 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1519_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1519_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
